Somatic mutation profile of tumor specimen C3L-09400-02 (aliquot CPT0478200006) from CPTAC case C3L-09400, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 79.0 years (28,867 days).
Specimen C3L-09400-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7247e27d-0805-4273-a13a-4a7c32747689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09400-31 (Blood Derived Normal), aliquot CPT0475840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bcfd89b-6ee2-47d7-9061-a5a7171079db

The open-access MAF lists 145 somatic variants for this specimen: 105 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 36, Nonsense Mutation 8, Frame Shift Ins 3, Intron 3, In Frame Del 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 82/283 reads (29%) | catalogued as rs1253151209, CM123456, COSV56236427; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 75/302 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 36/269 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TMLHE | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 78/566 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782785654, COSV57686403; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.2392A>G p.N798D | Missense Mutation (SNP) | VAF 151/493 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.429); catalogued as rs751152004; called by muse, mutect2, varscan2
- AMBRA1 | c.3601G>A p.A1201T (on ENST00000458649 / NM_001367468.1; = p.A1111T on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/610 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs144388436; called by muse, mutect2, varscan2
- ANK1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 79/581 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779607492, COSV55875316, COSV55876374; called by muse, mutect2, varscan2
- CNTN6 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99052077; called by muse, mutect2, varscan2
- DCAF1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); catalogued as rs983271767, COSV60042763; called by muse, mutect2, varscan2
- DENND2C | c.1231G>A p.V411I (on ENST00000393274 / NM_001256404.2; = p.V354I on NM_198459.4) | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs1249657532; called by muse, mutect2
- DNAH2 | c.8318G>A p.R2773H | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374110523; called by muse, mutect2, varscan2
- EDC4 | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 85/505 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745369392, COSV59303216; called by muse, mutect2, varscan2
- GALNT15 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 77/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433388632; called by muse, mutect2, varscan2
- GOLGA7 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs146085726, COSV63299505; called by muse, mutect2, varscan2
- GPRIN1 | c.1544C>T p.T515M | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs772230473; called by muse, mutect2, varscan2
- GRM4 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100947042; called by muse, mutect2, varscan2
- IRAG2 | c.4339C>T p.R1447* (on ENST00000636465; = p.R492* on NM_006152.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 38/225 reads (17%) | catalogued as rs146082101; called by muse, mutect2, varscan2
- KCNK7 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752136574; called by muse, mutect2, varscan2
- KCNU1 | c.2843C>A p.A948E | Missense Mutation (SNP) | VAF 63/477 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV101299032; called by muse, mutect2, varscan2
- KDM6A | c.3332G>C p.R1111P | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1457797612, COSV65036955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF4A | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs35473790, COSV65541997; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1690G>T p.V564F | Missense Mutation (SNP) | VAF 66/459 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); catalogued as COSV99169823; called by muse, mutect2, varscan2
- MS4A1 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs763383703, COSV61942069; called by muse, mutect2, varscan2
- MSH4 | c.539A>C p.N180T | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV54204787; called by muse, mutect2
- MUC16 | c.1387A>C p.T463P | Missense Mutation (SNP) | VAF 80/457 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV101199353; called by muse, mutect2, varscan2
- NTRK1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs758490619, COSV62327124; called by muse, mutect2, varscan2
- NUGGC | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs374292249; called by muse, mutect2, varscan2
- NXPE1 | c.1406C>T p.P469L (on ENST00000424269; = p.P327L on NM_152315.5) | Missense Mutation (SNP) | VAF 65/387 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52626914; called by muse, mutect2, varscan2
- OR4C12 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV58859624, COSV58860140; called by muse, mutect2, varscan2
- PAN3 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as rs1198236924; called by muse, mutect2, varscan2
- PLXNA4 | c.3793C>T p.R1265C | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100322839, COSV58116075; called by muse, mutect2, varscan2
- PNMA1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 85/408 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as COSV99679273; called by muse, mutect2, varscan2
- POTEF | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as rs748161177, COSV62542849; called by muse, mutect2
- PTPN4 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs147821849; called by muse, mutect2, varscan2
- PTPRD | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100645074, COSV61931602; called by muse, mutect2, varscan2
- RNF40 | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 81/488 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs542846699, COSV61214557; called by muse, mutect2, varscan2
- SBK2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 100/507 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs750164921; called by muse, mutect2, varscan2
- SIGIRR | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100230104; called by muse, mutect2, varscan2
- SIM2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 73/414 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs373021150; called by muse, mutect2, varscan2
- SLC39A3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 92/425 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs376600938; called by muse, varscan2
- SLITRK5 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 76/431 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898332694; called by muse, mutect2, varscan2
- SPDYE4 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs577856472; called by muse, mutect2, varscan2
- SPTBN5 | c.5858G>A p.R1953H | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs747944189, COSV100311539; called by muse, mutect2, varscan2
- STAG3 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750293273; called by muse, mutect2, varscan2
- TACR3 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201065494; called by muse, mutect2, varscan2
- TLNRD1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 69/470 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs757958625; called by muse, mutect2, varscan2
- TRIM9 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 86/478 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV53613244; called by muse, mutect2, varscan2
- TRRAP | c.1640G>T p.R547L | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100722512; called by muse, mutect2, varscan2
- TSKU | c.346A>T p.S116C | Missense Mutation (SNP) | VAF 85/471 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289987; called by muse, mutect2, varscan2
- TTLL2 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs1223233905, COSV53444642; called by muse, mutect2, varscan2
- UGGT2 | c.3113A>C p.K1038T | Missense Mutation (SNP) | VAF 60/354 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV65074564; called by muse, mutect2, varscan2
- ZNF865 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 112/581 reads (19%) | SIFT deleterious (0.04); catalogued as rs1482971604; called by muse, mutect2, varscan2
- ZSCAN22 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 59/521 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145454805; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4748G>A p.R1583K | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAZ2A | c.4048_4051del p.S1350Lfs*10 | Frame Shift Del (DEL) | VAF 54/414 reads (13%) | called by pindel, varscan2
- CCDC74A | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CDON | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CLIC6 | c.1886A>C p.K629T (on ENST00000360731 / NM_001317009.2; = p.K611T on NM_053277.3) | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CPT2 | c.1974T>G p.S658R | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CROT | c.1621C>T p.L541F | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTTNBP2 | c.3910G>A p.V1304M | Missense Mutation (SNP) | VAF 68/349 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CUL4B | c.2111T>G p.L704R | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CUX1 | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 91/530 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND4C | c.4399A>G p.I1467V (on ENST00000434457 / NM_001330640.2; = p.I1418V on NM_017925.7) | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBPL | c.615T>G p.F205L | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELF3 | c.922_923dup p.E309Pfs*17 | Frame Shift Ins (INS) | VAF 69/438 reads (16%) | called by pindel, varscan2
- FAM240B | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 105/318 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FYB2 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GHRHR | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 37/221 reads (17%) | called by muse, mutect2, varscan2
- GRM5 | c.1899C>A p.F633L | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HOXA13 | c.877A>T p.K293* | Nonsense Mutation (SNP) | VAF 65/426 reads (15%) | called by muse, mutect2, varscan2
- IFIH1 | c.2260_2261dup p.I755* | Frame Shift Ins (INS) | VAF 54/371 reads (15%) | called by mutect2, pindel, varscan2
- IGSF21 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA9 | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 56/286 reads (20%) | called by muse, mutect2, varscan2
- KRT36 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- LRRC6 | c.1061T>G p.L354R | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MALRD1 | c.4157T>G p.F1386C | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2A1 | c.2156A>C p.K719T | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAST1 | c.3982G>A p.V1328I | Missense Mutation (SNP) | VAF 102/517 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKI67 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- NCAM2 | c.1303A>T p.R435* | Nonsense Mutation (SNP) | VAF 44/248 reads (18%) | called by muse, mutect2, varscan2
- NELL2 | c.860G>T p.W287L | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, varscan2
- OR5AC2 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PAPPA2 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 88/451 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP9 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 62/375 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNLIP | c.77G>C p.C26S | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PPDPFL | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R3A | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- RAD54L2 | c.1853_1854dup p.C619Vfs*26 | Frame Shift Ins (INS) | VAF 41/197 reads (21%) | called by mutect2, varscan2
- REST | c.141_143del p.I47del | In Frame Del (DEL) | VAF 40/298 reads (13%) | called by pindel, varscan2
- RMC1 | c.1613T>C p.L538S | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SLITRK2 | c.222G>C p.L74F | Missense Mutation (SNP) | VAF 96/568 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYTL5 | c.1373A>G p.N458S | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TCEAL2 | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 56/674 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- TM4SF1 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TRRAP | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 48/305 reads (16%) | called by muse, mutect2, varscan2
- UGP2 | c.1132A>T p.S378C | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UROC1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- USHBP1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZIC1 | c.1172C>A p.S391* | Nonsense Mutation (SNP) | VAF 57/317 reads (18%) | called by muse, mutect2, varscan2
- ZNF391 | c.268T>C p.S90P | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZNF729 | c.2024A>C p.K675T | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF763 | c.1055C>T p.P352L (on ENST00000358987 / NM_001367172.2; = p.P355L on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/341 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ZNF814 | c.2198C>G p.A733G | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSCAN30 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 75/519 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AL772284.1 | c.219C>T p.N73= | Silent (SNP) | VAF 146/554 reads (26%) | catalogued as rs1184318390; called by muse, varscan2
- ARSB | c.864G>A p.G288= | Silent (SNP) | VAF 59/283 reads (21%) | catalogued as rs1440081063; called by muse, mutect2, varscan2
- ATP10A | c.714C>T p.N238= | Silent (SNP) | VAF 64/368 reads (17%) | catalogued as rs144385441, COSV63519808; called by muse, mutect2, varscan2
- ATP7B | c.3594C>G p.V1198= | Silent (SNP) | VAF 77/396 reads (19%) | called by muse, mutect2, varscan2
- BMP1 | c.1131C>T p.Y377= | Silent (SNP) | VAF 56/367 reads (15%) | catalogued as rs564392614; called by muse, mutect2, varscan2
- C2CD4A | c.693G>A p.P231= | Silent (SNP) | VAF 146/733 reads (20%) | catalogued as rs1345853836; called by muse, mutect2, varscan2
- CSMD1 | c.8148T>G p.T2716= (on ENST00000520002; = p.T2715= on NM_033225.6) | Silent (SNP) | VAF 52/371 reads (14%) | catalogued as COSV100155330, COSV59349568; called by muse, mutect2, varscan2
- DCAF12L2 | c.306G>A p.A102= | Silent (SNP) | VAF 233/780 reads (30%) | catalogued as COSV63582487, COSV63584428; called by muse, mutect2, varscan2
- DLG4 | c.1659C>T p.S553= (on ENST00000399506 / NM_001321075.3; = p.S596= on NM_001365.4) | Silent (SNP) | VAF 60/261 reads (23%) | catalogued as rs372194148; called by muse, mutect2, varscan2
- DNAH17 | c.4641C>T p.P1547= | Silent (SNP) | VAF 38/345 reads (11%) | catalogued as rs748451550; called by muse, mutect2, varscan2
- ELOVL1 | c.219C>T p.S73= | Silent (SNP) | VAF 43/229 reads (19%) | called by muse, mutect2, varscan2
- ESPN | c.2718G>A p.T906= | Silent (SNP) | VAF 129/568 reads (23%) | called by muse, mutect2, varscan2
- FAM43B | c.552G>A p.A184= | Silent (SNP) | VAF 139/658 reads (21%) | called by muse, mutect2, varscan2
- GCNA | c.480C>T p.D160= | Silent (SNP) | VAF 108/664 reads (16%) | catalogued as rs184215123, COSV65466841; called by muse, varscan2
- KAT8 | c.1376G>A p.*459= | Silent (SNP) | VAF 93/473 reads (20%) | called by muse, mutect2, varscan2
- KIF26B | c.5055C>T p.A1685= | Silent (SNP) | VAF 92/708 reads (13%) | catalogued as rs1367750982; called by muse, mutect2, varscan2
- LACTBL1 | c.1227C>T p.R409= (on ENST00000618559; = p.R454= on NM_001289974.2) | Silent (SNP) | VAF 102/561 reads (18%) | called by muse, mutect2, varscan2
- LRTM1 | c.597C>A p.V199= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as COSV55582301; called by muse, mutect2, varscan2
- NINL | c.2112C>T p.P704= | Silent (SNP) | VAF 89/499 reads (18%) | catalogued as rs146085894; called by muse, mutect2, varscan2
- OR52E5 | c.609C>T p.F203= | Silent (SNP) | VAF 44/282 reads (16%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.2613C>T p.V871= | Silent (SNP) | VAF 51/233 reads (22%) | catalogued as rs571898721; called by muse, mutect2, varscan2
- PDZD2 | c.7161C>T p.D2387= | Silent (SNP) | VAF 84/462 reads (18%) | catalogued as rs184833310; called by muse, mutect2, varscan2
- PLB1 | c.3882G>A p.V1294= | Silent (SNP) | VAF 52/323 reads (16%) | catalogued as rs150980352; called by muse, mutect2, varscan2
- PPIL4 | c.1374A>G p.K458= | Silent (SNP) | VAF 67/360 reads (19%) | called by muse, mutect2, varscan2
- PPP2R2B | c.666G>A p.T222= (on ENST00000394409; = p.T288= on NM_181674.2) | Silent (SNP) | VAF 73/394 reads (19%) | catalogued as rs779770096, COSV60752666; called by muse, mutect2, varscan2
- PRC1 | c.27G>A p.E9= | Silent (SNP) | VAF 38/262 reads (15%) | catalogued as rs1238185458; called by muse, mutect2, varscan2
- SERINC3 | c.1038C>T p.L346= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as rs746932898; called by muse, mutect2, varscan2
- SERPINH1 | c.33C>T p.C11= | Silent (SNP) | VAF 20/436 reads (5%) | called by muse, mutect2
- SLC6A11 | c.108G>A p.A36= | Silent (SNP) | VAF 92/526 reads (17%) | catalogued as COSV54398833; called by muse, mutect2, varscan2
- SLIT1 | c.3843C>T p.S1281= | Silent (SNP) | VAF 48/244 reads (20%) | catalogued as rs759559857; called by muse, mutect2, varscan2
- SPNS1 | c.1143C>T p.I381= | Silent (SNP) | VAF 49/298 reads (16%) | catalogued as rs1244180956; called by muse, mutect2, varscan2
- SPRY3 | c.81C>T p.Y27= | Silent (SNP) | VAF 94/667 reads (14%) | catalogued as rs192786119, COSV57142441; called by muse, mutect2, varscan2
- TIGD5 | c.438C>T p.L146= | Silent (SNP) | VAF 116/849 reads (14%) | catalogued as rs755119403; called by muse, mutect2, varscan2
- TRRAP | c.10167G>A p.S3389= (on ENST00000359863 / NM_001244580.1; = p.S3360= on NM_003496.3) | Silent (SNP) | VAF 76/492 reads (15%) | catalogued as rs780273644, COSV62845015, COSV62847610; called by muse, mutect2, varscan2
- TTC39B | c.1401T>G p.T467= | Silent (SNP) | VAF 28/229 reads (12%) | called by muse, mutect2, varscan2
- VPS13B | c.3333G>A p.P1111= | Silent (SNP) | VAF 45/300 reads (15%) | catalogued as rs367791771; called by muse, varscan2
- C2CD6 | c.1581+3814del | Intron (DEL) | VAF 27/185 reads (15%) | called by mutect2, pindel, varscan2
- NAV3 | c.2024-12653_2024-12634del | Intron (DEL) | VAF 77/350 reads (22%) | called by mutect2, pindel, varscan2
- OTUD4 | c.*2639T>C | 3'UTR (SNP) | VAF 68/397 reads (17%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+123dup | Intron (INS) | VAF 40/194 reads (21%) | catalogued as rs17844337; called by mutect2, varscan2
